Somatic mutation profile of tumor specimen ALCH-B284-TTP1-A (aliquot ALCH-B284-TTP1-A-1-0-D-A775-36) from ALCHEMIST case ALCH-B284, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.4 years (19,497 days).
Specimen ALCH-B284-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d70f2206-625b-4cc8-8aa1-be541a39ee00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B284-NB1-A (Blood Derived Normal), aliquot ALCH-B284-NB1-A-1-0-D-A775-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b95829bb-a9af-4b61-b52e-d302269bd7ee

The open-access MAF lists 58 somatic variants for this specimen: 42 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 11, Nonsense Mutation 4, RNA 2, 5'Flank 2, Frame Shift Del 2, Splice Region 1, Intron 1, In Frame Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 61/355 reads (17%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 40/230 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AHNAK | c.8393C>G p.S2798* | Nonsense Mutation (SNP) | VAF 20/318 reads (6%) | catalogued as COSV99948421; called by muse, mutect2
- BHLHE22 | c.221_260del p.G74Afs*18 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | catalogued as rs778657494; called by mutect2, pindel
- C1D | c.331A>T p.R111* | Nonsense Mutation (SNP) | VAF 39/265 reads (15%) | catalogued as COSV63413985; called by muse, mutect2, varscan2
- CD72 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs770122832, COSV52410274; called by muse, mutect2, varscan2
- FBXL7 | c.1444G>A p.V482I | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1219818114, COSV61641181; called by muse, mutect2
- FBXO32 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs747151549, COSV54891200; called by muse, mutect2
- GALNT13 | c.1487G>T p.C496F | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67232746; called by muse, mutect2
- LAMC1 | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.057); catalogued as COSV51171555; called by muse, mutect2
- PCDH11X | c.2863C>T p.P955S | Missense Mutation (SNP) | VAF 30/601 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53446949; called by muse, mutect2
- POU4F2 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55585061; called by muse, mutect2, varscan2
- TIMMDC1 | c.659G>A p.R220K | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.056); catalogued as COSV51785973; called by muse, mutect2
- TMEM185B | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1028302451; called by muse, mutect2
- UBR1 | c.2512del p.Y838Tfs*41 | Frame Shift Del (DEL) | VAF 35/214 reads (16%) | catalogued as COSV51927509; called by mutect2, pindel, varscan2
- VIT | c.1585G>A p.D529N (on ENST00000389975 / NM_001177969.1; = p.D544N on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs143152433; called by muse, mutect2
- ZC3H11A | c.1093C>T p.L365F | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.898); catalogued as COSV59750946; called by muse, mutect2
- ZNF800 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | catalogued as COSV56177876; called by muse, mutect2
- ABHD4 | c.140A>T p.Y47F | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ACSS2 | c.2063T>C p.V688A | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); called by muse, mutect2
- AHNAK | c.4961C>G p.S1654C | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANKS1B | c.796C>G p.L266V | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ARFGEF3 | c.3547T>G p.F1183V | Missense Mutation (SNP) | VAF 43/241 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ATP2B1 | c.1055C>A p.A352E | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- BACE2 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 30/344 reads (9%) | called by muse, mutect2
- CCDC166 | c.569T>G p.F190C | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.106); called by muse, mutect2
- CEP68 | c.2007+6A>C | Splice Region (SNP) | VAF 39/377 reads (10%) | called by muse, mutect2, varscan2
- DKC1 | c.629A>G p.E210G | Missense Mutation (SNP) | VAF 32/304 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, mutect2
- DYTN | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 19/275 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2
- EFNB1 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 18/526 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.109); called by muse, mutect2
- H4C9 | c.191A>G p.E64G | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- IRF4 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPR3 | c.679T>A p.F227I | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2
- KIF4A | c.1330A>G p.K444E | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- MCHR1 | c.562A>G p.I188V | Missense Mutation (SNP) | VAF 22/444 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); called by muse, mutect2
- RIPK4 | c.2269dup p.L757Pfs*21 (on ENST00000352483; = p.L709Pfs*21 on NM_020639.3) | Frame Shift Ins (INS) | VAF 23/123 reads (19%) | called by mutect2, pindel, varscan2
- RTL1 | c.2147T>C p.I716T | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- SET | c.659T>C p.V220A (on ENST00000372692 / NM_001374326.1; = p.V207A on NM_003011.4) | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- SGCZ | c.620+1G>A p.X207_splice | Splice Site (SNP) | VAF 8/165 reads (5%) | called by muse, mutect2
- TLR8 | c.2302G>A p.E768K (on ENST00000218032 / NM_138636.5; = p.E786K on NM_016610.4) | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT tolerated (0.92); PolyPhen benign (0.022); called by muse, mutect2
- VPS28 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2
- ZNF182 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2
- ARMH4 | c.1482T>C p.T494= | Silent (SNP) | VAF 81/394 reads (21%) | catalogued as COSV99957775; called by muse, mutect2, varscan2
- CARMIL3 | c.3972C>T p.P1324= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs749926699; called by muse, mutect2, varscan2
- CORIN | c.189G>T p.V63= | Silent (SNP) | VAF 6/152 reads (4%) | called by muse, mutect2
- KCNG1 | c.1053G>A p.L351= | Silent (SNP) | VAF 47/186 reads (25%) | called by muse, mutect2, varscan2
- NAXE | c.18G>A p.A6= | Silent (SNP) | VAF 25/266 reads (9%) | called by muse, mutect2
- NPHS1 | c.3351C>T p.S1117= | Silent (SNP) | VAF 18/422 reads (4%) | called by muse, mutect2
- NUP62 | c.1485G>T p.L495= | Silent (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2
- PRPF19 | c.348C>T p.V116= | Silent (SNP) | VAF 42/271 reads (15%) | catalogued as rs1450675372; called by muse, mutect2, varscan2
- REXO1 | c.1473G>A p.K491= | Silent (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- TMED4 | c.210C>T p.P70= | Silent (SNP) | VAF 14/236 reads (6%) | called by muse, mutect2
- XPO5 | c.3180G>T p.L1060= | Silent (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- AC104472.1 | n.308T>G | RNA (SNP) | VAF 4/32 reads (13%) | catalogued as rs1559978364; called by mutect2, varscan2
- FBXW9 | chr19:12696587 C>G | 5'Flank (SNP) | VAF 21/104 reads (20%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.1974G>T | RNA (SNP) | VAF 14/296 reads (5%) | called by muse, mutect2
- PHACTR1 | c.251-119500G>C | Intron (SNP) | VAF 34/165 reads (21%) | catalogued as COSV60675118; called by muse, varscan2
- RNF32 | chr7:156640197 G>A | 5'Flank (SNP) | VAF 18/207 reads (9%) | called by muse, mutect2
